HCMI case HCM-BROD-0485-C15 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Esophagus. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/a43460d9-c2cd-4656-bc5a-d2ba54bad91d

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1970; Vital status: Alive.

Diagnoses (2)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C15.9; Tissue or organ of origin: Esophagus, NOS; Classification of tumor: primary; Age at diagnosis: 46.5 years (16,967 days); AJCC staging edition: 7th; AJCC clinical stage: Stage IV; AJCC pathologic stage: Stage IV; Tumor grade: G2; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: no; Prior treatment: Yes; Esophageal columnar dysplasia degree: Negative/ No Dysplasia; Esophageal columnar metaplasia present: No; Gastric esophageal junction involvement: Yes; Goblet cells columnar mucosa present: No; Sites of involvement: Stomach.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 3 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil + Irinotecan + Leucovorin Calcium; Treatment intent type: Neoadjuvant; Regimen or line of therapy: FOLFIRI; Days to treatment start: 33 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil + Leucovorin Calcium + Oxaliplatin; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Regimen or line of therapy: FOLFOX; Days to treatment start: 33 days; Days to treatment end: 259 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil + Leucovorin Calcium + Oxaliplatin; Treatment intent type: Neoadjuvant; Regimen or line of therapy: FOLFOX; Days to treatment start: 33 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil + Irinotecan + Leucovorin Calcium; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Regimen or line of therapy: FOLFIRI; Days to treatment start: 260 days; Days to treatment end: 665 days (1.8 years).
   Recorded as not given: adjuvant Immunotherapy (Including Vaccines), for residual disease; neoadjuvant Radiation Therapy, NOS; adjuvant Radiation Therapy, NOS, for residual disease; adjuvant Targeted Molecular Therapy, for residual disease.
2. Adenocarcinoma, metastatic, NOS: ICD-O-3 morphology code: 8140/6; ICD-10 code: C78.9; Tissue or organ of origin: Esophagus, NOS; Site of resection or biopsy: Stomach, NOS; Classification of tumor: metastasis; Age at diagnosis: 48.3 years (17,624 days); Days to diagnosis: 657 days (1.8 years); Esophageal columnar dysplasia degree: Negative/ No Dysplasia; Esophageal columnar metaplasia present: No; Gastric esophageal junction involvement: Yes; Goblet cells columnar mucosa present: No.

Follow-up (2 entries)
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Stomach, NOS; Days to progression: 0 days.
- Days to follow up: 715 days (2.0 years); Disease response: Complete Response; Progression or recurrence: No.

Other clinical attributes
- Timepoint category: Initial Diagnosis; BMI: 22.

Exposures
- Alcohol intensity: Non-Drinker.

Family history
- Relationship type: First Degree Relative, NOS.

Biospecimens (3 samples)
- Sample HCM-BROD-0485-C15-06A: Sample type: Human Tumor Original Cells; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Human Original Cells; Preservation method: Frozen.
- Sample HCM-BROD-0485-C15-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
- Sample HCM-BROD-0485-C15-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 5.
